Gene-level copy-number profile of tumor specimen TCGA-GU-A42R-01A from TCGA case TCGA-GU-A42R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.8 years (25,134 days).
Specimen TCGA-GU-A42R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.968b965e-3237-44ae-aa19-388dbebc9693.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-A42R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 457 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/faa1ba08-68cf-4b34-ad6d-2261dea170d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 8,917; copy number 2: 29,627; copy number 3: 17,093; copy number 4: 4,226; copy number 5: 114; copy number 6: 102.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-A42R-01A-11D-A23L-01): tumor purity 0.78, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:82,010,665–82,461,177, 12 genes (within-gene range 0–2): NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1, VAMP9P, AC124016.2, HNRNPD, AC124016.1, IGBP1P4, SNORD42, HNRNPDL, ENOPH1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–24,088,051, 26 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr16:3,500,976–3,717,553, 10 genes (within-gene range 0–1): CLUAP1, AC004494.2, NLRC3, AC004494.1, AC006111.1, SLX4, DNASE1, AC006111.2, TRAP1, AC006111.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 216 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:157,204,182–157,366,075, 1 gene, copy number 5 (within-gene range 2–5): GRIA2.
- chr4:157,568,731–158,202,877, 17 genes, copy number 5: AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1.
- chr9:14,475–492,248, 12 genes, copy number 5 (within-gene range 3–5): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1.
- chr9:477,750–478,423, 1 gene, copy number 5: RPL12P25.
- chr17:28,275,986–29,707,090, 98 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:29,639,627–29,716,685, 4 genes, copy number 6: AC104564.1, RNU6-920P, AC104564.5, RPL21P123.
- chr19:27,638,483–32,073,809, 83 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,569. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
